CCDI case PBCCIK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8a3bae26-1008-4b85-bb67-309f8a0a9fc4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,147 days).

Biospecimens (3 samples)
- Sample 0DOJUU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOJW1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOJY5: Tissue type: Tumor; Specimen type: Solid Tissue.
